Gene-level copy-number profile of tumor specimen TCGA-HD-7229-01A from TCGA case TCGA-HD-7229, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 60.4 years (22,076 days).
Specimen TCGA-HD-7229-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.f8be7bc9-dbbd-4cc7-93eb-066f3aa522db.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HD-7229-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d12ce7d4-7d55-4568-8046-8b306da10a41

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 7,670; copy number 2: 43,004; copy number 3: 6,905; copy number 4: 1,014; copy number 5: 194; copy number 6: 616; copy number 7: 98; copy number 8: 225; copy number 9: 43; copy number 12: 38.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HD-7229-01A-11D-2010-01): tumor purity 0.57, ploidy 2.17, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,556,069–11,771,350, 3 genes (within-gene range 0–1): VGLL4, AC022001.2, AC022001.3.
- chr4:186,426,546–186,726,722, 4 genes (within-gene range 0–2): AC018709.1, RNU6-1055P, MTNR1A, FAT1.
- chr9:9,442,060–9,442,380, 1 gene: RN7SL5P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,214 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:63,635,802–63,779,336, 1 gene, copy number 6: PHF3.
- chr6:63,797,189–63,857,769, 3 genes, copy number 6: AL354719.1, SCAT8, GCNT1P4.
- chr6:99,918,519–143,387,409, 612 genes, copy number 6 (broad region; genes not listed).
- chr7:70,972–23,105,703, 360 genes, copy number 7–12 (broad region; genes not listed).
- chr7:23,129,178–23,129,841, 1 gene, copy number 7: AK3P3.
- chr7:28,615,097–30,367,689, 37 genes, copy number 9: AC005105.1, TRIL, AC005013.1, AC005162.2, AC005162.1, CPVL, CPVL-AS1, AC005232.1, AC004593.2, CHN2, AC004593.1, CHN2-AS1, NANOGP4, AC007255.1, GTF3C6P3, PRR15, ZNRF2P2, TMSB4XP3, DPY19L2P3, MIR550A3, WIPF3, AC004912.1, SCRN1, FKBP14-AS1, FKBP14, PLEKHA8, AC007285.1, AC007036.4, AC007036.5, MTURN, AC007036.2, AC007036.3, RPS27P16, AC007036.1, ZNRF2, MIR550A1, MIR550B1.
- chr7:30,371,508–30,372,741, 1 gene, copy number 9: AC006978.1.
- chr7:39,404,590–43,729,717, 55 genes, copy number 5–9: POU6F2-AS1, AC011290.1, YAE1, AC011290.2, AC004837.3, AC004837.1, AC004837.4, RALA, AC004837.2, LINC00265, RNU6-719P, AC004987.3, CICP22, AC004987.2, AC004987.1, SSBL3P1, RWDD4P2, RN7SL496P, AC072061.1, CDK13, AC006023.2, AC006023.1, MPLKIP, Y_RNA, SUGCT, THUMPD3P1, SUGCT-AS1, AC005160.1, LINC01450, LINC01449, INHBA, INHBA-AS1, GLI3, HMGN2P30, LINC01448, TCP1P1, AC010132.1, AC010132.4, C7orf25, AC010132.3, PSMA2, AC010132.2, MRPL32, AC005537.1, Y_RNA, HECW1, HECW1-IT1, MIR3943, RNU7-35P, RNU6-575P, AC004692.2, AC004692.1, LUARIS, STK17A, COA1.
- chr7:43,767,290–43,767,599, 1 gene, copy number 9: AC005189.1.
- chr9:14,475–7,961,224, 139 genes, copy number 5 (broad region; genes not listed).
- chr9:8,700,595–8,864,772, 4 genes, copy number 5: AL583805.2, AL583805.1, RNU7-185P, PTPRD-AS1.

Autosomal genes at a single copy (total copy number 1): 5,284. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
